Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OU, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OU-01A (Primary Tumor).

[page 1 of 2]
PROCEDURE: SPHS

Esophageal cancer, GERD x 20 years with adenocarcinoma and cholelithiasis. Also has history of AFIB, hypertension, type II diabetes, congestive heart failure, coronary artery disease, MI, MVA in with head injury. Clinical diagnosis: Esophageal cancer. Operative Procedure: Status post

1CD-0-3

adenocarcinoma, NOS 8140/3
Site: esophagus, distal third
C15.5

PROCEDURE: SPGD

1. "Gallbladder" Received in a medium container is a 7.1 x 3.2 x 2.4 cm gallbladder with unremarkable purple-gray serosa. The lumen is partly filled with dark green viscous bile and multiple black, multifaceted stones. The stones are in the fundus and body and are seen up to 1.7 cm in greatest dimensions, crushing with ease. The mucosa is dark green, velvety and the wall thickness averages 0.2 cm. The cystic duct is patent.

Cassette 1. Gallbladder.

2. "Distal esophagus proximal stomach" Received in formalin in a large container is a previously opened, distal esophagus and proximal stomach that is 12.9 x 8.5 x 4.4 cm in overall dimensions. There is a small amount of adherent perigastric adipose tissue. The esophageal margin is stapled, as well as the cardiac margin. The distal esophageal adventitia is inked green and the cardiac serosa is inked black. The esophageal adventitia is focally firm, as well as the gastric serosa near the esophagogastric junction. Arising in the esophagogastric junction is a 3.3 x 1.8 cm circumferential firm mass. The centrally ulcerated tumor appears to involve 0.6 cm of the esophageal mucosa with the remaining 2.7 cm located in the gastric cardia. The cut surfaces through the tumor shows a perforating muscularis and serosa, involving the perigastric/adventitial fatty tissue. It is slightly puckering the gastric serosa and perigastric fat. The remaining esophageal mucosa is unremarkable, as well as the remaining gastric mucosa. Lymph node candidates are retrieved from the periesophageal and perigastric fatty tissue up to 1.6 cm in greatest dimensions. The cut surface of the largest is gray-white, focally hemorrhagic and partly replaced by fatty tissue.

2A-B. Bisected full-thickness section EGJ tumor.

2C-D. Bisected full-thickness section of EGJ tumor.

2E. Additional section of tumor to esophageal mucosa. (

2F. Nine whole lymph node candidate.

2G. One bisected lymph node candidate. (fat retained)

3. "Cervical esophageal margin" Received in formalin in a small container is a 0.8 cm segment of gray-brown cervical tissue. The possible margin is stapled, and the distal margin is opened. The adventitia and mucosa are unremarkable.

Cassette 3. Cervical esophageal margin. (, staple line retained)

4. "Celiac lymph node" Received in formalin in a small container are two ovoid portions of fatty tissue. The smaller is 1.1 cm in greatest dimension and the larger is 1.4 cm in greatest dimensions. The smallest portion is only fatty tissue with no lymph node candidate readily seen. The larger portion has a single 1 cm lymph node candidate which is gray-white on the cut surface.

hw
10/9/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

There is a small amount of adherent fatty tissue.
Cassette 4. Bisected lymph node candidate. (fat retained)

PROCEDURE: SPMI

ESOPHAGUS CARCINOMA

LOCATION: Lower.

SIZE: 3.3 cm.

HAS IT BEEN TREATED: No.

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa.

DEPTH OF INVASION: Adventitia.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/12.

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: No.

T3 NO MX

PROCEDURE: SPDY

2-3. Distal esophagus and proximal stomach, resections: Esophageal adenocarcinoma (3.3 cm) arising in Barrett's mucosa, involving gastroesophageal junction, extending to adventitia. Margins free of tumor. Eleven lymph nodes negative for neoplasm (0/11). See template.

1. Gallbladder, resection: Chronic cholecystitis and cholelithiasis.

4. Lymph node, celiac, resection: One lymph node negative for neoplasm (0/1).

Source: NCI Genomic Data Commons file d78dbc67-767d-4f3b-a4a6-c61019b2218c (TCGA-L5-A4OU.ECBFB459-047F-468F-82D4-4747A7D64FDF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).